Somatic mutation profile of tumor specimen MP2PRT-PAUGTX-TBP1-A (aliquot MP2PRT-PAUGTX-TBP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUGTX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.8 years (2,466 days).
Specimen MP2PRT-PAUGTX-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fb71234-4da7-4e4d-9e0c-ec3dfd220e7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUGTX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUGTX-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c145ca5c-ed31-42f7-a4c5-423fac3a922d

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 82/280 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CFAP46 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.711); catalogued as rs1029661203, COSV63952274; called by muse, mutect2, varscan2
- NEFL | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 36/478 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.269); catalogued as rs1415523458, COSV55337798; called by muse, mutect2
- NRXN3 | c.1042A>G p.I348V | Missense Mutation (SNP) | VAF 108/482 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1400098791; called by muse, mutect2, varscan2
- OR52N2 | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 98/360 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs1348199120, COSV57677773; called by muse, mutect2, varscan2
- TAF1L | c.4208C>T p.T1403M | Missense Mutation (SNP) | VAF 111/365 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs778395226, COSV54260622; called by muse, mutect2, varscan2
- CCL18 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 123/537 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EIF5B | c.31G>C p.D11H | Missense Mutation (SNP) | VAF 106/378 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZC3H7B | c.308_328dup p.E103_L109dup | In Frame Ins (INS) | VAF 38/212 reads (18%) | called by mutect2, varscan2
- ABRA | c.243G>A p.S81= | Silent (SNP) | VAF 109/370 reads (29%) | catalogued as rs766133371, COSV61732524; called by muse, mutect2, varscan2
- GAREM1 | c.1707C>T p.S569= | Silent (SNP) | VAF 92/488 reads (19%) | called by muse, mutect2, varscan2
- IGKV1OR2-108 | c.352T>G p.*118= | Silent (SNP) | VAF 38/122 reads (31%) | called by muse, mutect2, varscan2
- IGKV1OR2-108 | c.353T>C p.*118= | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as rs748598299; called by muse, mutect2, varscan2
